Gene-level copy-number profile of tumor specimen C3L-03984-01 (profiled together with C3L-03984-05) from CPTAC case C3L-03984, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 59.8 years (21,834 days).
Specimen C3L-03984-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c843d9a5-46f5-44a0-b126-8dc650eb41dd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03984-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/70866677-8750-4ec9-b55c-328f9bf34bb1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,111; copy number 2: 40,255; copy number 3: 9,881; copy number 4: 2,115; copy number 5: 1,451; copy number 6: 613; copy number 7: 118; copy number 8: 95; copy number 9: 166; copy number 11: 34; copy number 12: 42; copy number 13: 17.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:92,059,844–92,180,885, 2 genes (within-gene range 0–1): RNU4ATAC3P, FABP5P4.
- chr13:92,484,606–92,510,094, 2 genes (within-gene range 0–1): GPC5-IT1, MIR548AS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,536 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–158,100,262, 651 genes, copy number 5 (broad region; genes not listed).
- chr1:178,725,147–178,921,841, 1 gene, copy number 5 (within-gene range 4–5): RALGPS2.
- chr1:178,849,535–179,256,081, 12 genes, copy number 5: ANGPTL1, FAM20B, AL139132.1, TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8.
- chr4:37,001,772–39,285,810, 37 genes, copy number 5–6: LINC02616, AL136537.1, MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3, RNA5SP158, TLR10, TLR1, TLR6, FAM114A1, MIR574, TMEM156, KLHL5, AC079921.1, AC079921.2, WDR19.
- chr4:43,763,134–44,448,809, 6 genes, copy number 5 (within-gene range 3–5): AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475, KCTD8.
- chr4:51,843,000–58,118,070, 124 genes, copy number 5–12 (broad region; genes not listed).
- chr4:64,275,257–66,897,371, 28 genes, copy number 6: TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, LINC02232, AC107058.1, EFL1P2, AC096754.1, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3, RNU6-699P.
- chr4:143,184,917–143,557,486, 12 genes, copy number 5: USP38, AC097658.2, Y_RNA, GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1.
- chr4:143,559,472–143,561,460, 1 gene, copy number 5: GUSBP5.
- chr5:612,340–892,801, 8 genes, copy number 6 (within-gene range 2–6): CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9.
- chr5:1,173,141–1,634,005, 19 genes, copy number 6–12: CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2.
- chr5:2,261,859–5,490,220, 39 genes, copy number 6–8: AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1.
- chr5:7,396,138–10,777,062, 88 genes, copy number 6 (broad region; genes not listed).
- chr5:16,033,229–18,049,872, 63 genes, copy number 5 (broad region; genes not listed).
- chr5:25,087,450–28,287,807, 24 genes, copy number 6–7: LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, RNU4-43P, AC025475.1, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103.
- chr5:28,614,613–28,654,531, 2 genes, copy number 6: AC109472.1, RNU6-909P.
- chr5:108,727,825–114,668,410, 75 genes, copy number 5–8 (broad region; genes not listed).
- chr7:88,420,167–88,756,725, 1 gene, copy number 5 (within-gene range 4–5): AC002069.2.
- chr7:88,639,014–100,707,486, 264 genes, copy number 5–9 (broad region; genes not listed).
- chr7:107,201,372–109,999,624, 38 genes, copy number 5–7 (within-gene range 2–7): COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8.
- chr8:66,562,175–66,922,048, 8 genes, copy number 6–7 (within-gene range 4–7): MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2.
- chr9:64,817,870–64,889,063, 3 genes, copy number 6: AL359955.1, AC125634.1, RNU6-1293P.
- chr12:12,310–1,788,674, 40 genes, copy number 5: DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14.
- chr12:3,606,633–6,866,632, 98 genes, copy number 5–9 (broad region; genes not listed).
- chr12:19,089,151–19,108,183, 2 genes, copy number 6: RPL7P6, MEF2BNBP1.
- chr12:24,212,421–27,161,393, 62 genes, copy number 7–9 (broad region; genes not listed).
- chr12:31,073,860–31,104,799, 1 gene, copy number 5 (within-gene range 3–5): DDX11.
- chr12:31,105,105–32,745,650, 57 genes, copy number 5 (within-gene range 2–5): AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P, DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1.
- chr19:27,638,483–32,244,083, 80 genes, copy number 8–13 (broad region; genes not listed).
- chr20:87,250–31,259,632, 544 genes, copy number 5–6 (broad region; genes not listed).
- chr20:47,826,969–49,278,426, 27 genes, copy number 5 (within-gene range 2–5): RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, LINC01522, LINC01523, AL139351.1, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1.
- chr20:51,098,138–56,406,362, 57 genes, copy number 5–12: AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1.
- chr20:57,311,854–58,715,410, 32 genes, copy number 6 (within-gene range 4–6): Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1.
- chr21:30,829,039–32,197,813, 20 genes, copy number 5: KRTAP7-1, KRTAP11-1, KRTAP19-8, UBE3AP2, TIAM1, AP000248.1, AP000563.1, AP000251.1, FBXW11P1, AP000253.1, SOD1, AP000254.1, AP000254.2, SCAF4, HMGN1P2, AP000255.1, TPT1P1, HUNK, HUNK-AS1, LINC00159.
- chr22:15,282,557–15,644,330, 12 genes, copy number 6–8: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, MED15P7.

Autosomal genes at a single copy (total copy number 1): 2,724. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
